RC case RC-B667 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0a59ec39-7fb0-46c6-8c93-2e0f31209bec

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1982; Vital status: Alive.

Diagnoses (1)
1. T-cell large granular lymphocytic leukemia: ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 33.6 years (12,255 days); Year of diagnosis: 2015; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Days to follow up: 329 days; Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 191 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85.9 kg; Height: 177.5 cm; BMI: 27.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Cervical Cancer.

Biospecimens (2 samples)
- Sample RC-B667-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B667-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
